Gene-level copy-number profile of tumor specimen TCGA-3B-A9I1-01A from TCGA case TCGA-3B-A9I1, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 56.5 years (20,629 days).
Specimen TCGA-3B-A9I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.af4bdf35-149f-479e-9945-b99e7c10e0b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9I1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1b7b58a-1416-4edc-aa63-c797732cc8cc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 480; copy number 2: 11,860; copy number 3: 26,930; copy number 4: 7,401; copy number 5: 12,072; copy number 6: 11; copy number 7: 973; copy number 8: 11; copy number 10: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9I1-01A-11D-A38Y-01): tumor purity 0.96, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,059 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,167,159–10,295,579, 9 genes, copy number 8: AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes, copy number 10 (within-gene range 5–10): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 8: AC139365.2, AC139365.1.
- chr14:18,333,726–61,550,976, 1,043 genes, copy number 7–10 (broad region; genes not listed).
- chr14:61,535,385–61,545,484, 1 gene, copy number 7: AL355916.2.

Autosomal genes at a single copy (total copy number 1): 478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
